Somatic mutation profile of tumor specimen TCGA-BS-A0V7-01A (aliquot TCGA-BS-A0V7-01A-21D-A122-09) from TCGA case TCGA-BS-A0V7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 48.8 years (17,810 days).
Specimen TCGA-BS-A0V7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3cfc3b8-860d-4d30-9ca4-3518f87f5022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0V7-10A (Blood Derived Normal), aliquot TCGA-BS-A0V7-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f2649d-4a9d-423c-b9ce-c869d9689381

The open-access MAF lists 57 somatic variants for this specimen: 52 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 4, Nonsense Mutation 3, Splice Site 1, Splice Region 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 16/114 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 20/216 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs140656187, COSV57258562; called by muse, mutect2
- KAT6A | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794000, COSV55907802; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 83/387 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 39/141 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 25/219 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.2975A>G p.E992G | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99802009; called by muse, mutect2
- ANO1 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV60283449; called by muse, mutect2, varscan2
- ARHGAP35 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351271; called by muse, mutect2
- C3 | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs146865006, COSV55571608, COSV55572798; called by muse, mutect2, varscan2
- CADPS | c.3902G>A p.R1301Q | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs755694732, COSV51891724, COSV99340302; called by muse, mutect2
- CDH18 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs755435892, COSV56915596; called by muse, mutect2, varscan2
- CFAP161 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs375754118, COSV54428952; called by muse, mutect2
- CNTNAP2 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100667929; called by muse, mutect2
- ENPP2 | c.1213C>T p.P405S (on ENST00000075322 / NM_001040092.3; = p.P457S on NM_006209.5) | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.822); catalogued as COSV50013138; called by muse, mutect2, varscan2
- ERCC1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99185340; called by muse, mutect2
- EVX2 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs538737983, COSV57963043, COSV57963216; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 44/445 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.693); catalogued as rs776040636, COSV100437133, COSV100437664; called by muse, mutect2
- GNL2 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 37/463 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100895018; called by muse, mutect2
- GPR174 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV52132111; called by muse, mutect2, varscan2
- GRM3 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100862661; called by muse, mutect2
- HCN3 | c.1658T>C p.I553T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs1315015251, COSV61360965; called by muse, mutect2, varscan2
- HSP90AB1 | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); catalogued as COSV100807130; called by muse, mutect2
- IGLV3-10 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs762379155; called by muse, mutect2
- IKZF4 | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV56267874; called by muse, mutect2, varscan2
- KALRN | c.5863T>C p.F1955L (on ENST00000360013 / NM_001024660.4; = p.F258L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52254624; called by muse, mutect2, varscan2
- MDH1B | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 50/562 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100982219; called by muse, mutect2
- MDN1 | c.16175C>T p.S5392F | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65520484; called by muse, mutect2, varscan2
- MORC4 | c.1597C>A p.P533T | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.399); catalogued as COSV55241255; called by muse, mutect2
- MUC16 | c.9044C>T p.T3015I | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as rs747450793, COSV101200330; called by muse, mutect2
- NEK11 | c.478A>C p.K160Q | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63580430; called by muse, mutect2, varscan2
- NISCH | c.4297G>A p.V1433I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs766139065, COSV58734943; called by mutect2, varscan2
- NOL4 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs140091305; called by muse, mutect2, varscan2
- NOLC1 | c.332G>C p.R111P | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs907473117, COSV64180276; called by muse, mutect2, varscan2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKLR | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs148435198, COSV61360968, COSV61361375; called by muse, mutect2, varscan2
- PRTG | c.2114C>T p.T705I | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV66837644; called by muse, mutect2, varscan2
- PTEN | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 117/567 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554893773, CM991079, COSV64292765, COSV64294921, COSV64304506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBBP5 | c.978+1G>T p.X326_splice | Splice Site (SNP) | VAF 26/273 reads (10%) | catalogued as COSV99196844; called by muse, mutect2
- RPS6KA6 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV53118634; called by muse, mutect2, varscan2
- RYR3 | c.10681C>T p.R3561C (on ENST00000389232; = p.R3562C on NM_001036.6) | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs779158082, COSV66785127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAF4 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 28/257 reads (11%) | catalogued as COSV54586170; called by muse, mutect2, varscan2
- SEC63 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.893); catalogued as COSV100938427, COSV64598359; called by muse, mutect2
- SNRPA | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV54680871; called by muse, mutect2, varscan2
- TFDP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64740014; called by muse, mutect2, varscan2
- TNFSF15 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 41/355 reads (12%) | catalogued as rs1334265183, COSV65010171; called by muse, mutect2, varscan2
- VPS35L | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 18/191 reads (9%) | catalogued as COSV99221106; called by muse, mutect2
- WLS | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52039901; called by muse, mutect2, varscan2
- ZNF804A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1436089805, COSV100168674; called by muse, mutect2
- CYRIA | c.268_269del p.K90Efs*8 | Frame Shift Del (DEL) | VAF 42/479 reads (9%) | called by mutect2, pindel
- EPHB4 | c.2946_2949dup p.A984Tfs*180 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- RRM2 | n.360C>A | Splice Region (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- CTAGE1 | c.9C>T p.P3= | Silent (SNP) | VAF 35/310 reads (11%) | catalogued as COSV101194459, COSV66943287; called by muse, mutect2, varscan2
- HERC2 | c.2700C>T p.T900= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs376492281; called by muse, mutect2, varscan2
- KMT2A | c.10815G>A p.G3605= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs1191156925, COSV63284660; called by muse, mutect2, varscan2
- ZBTB1 | c.87A>T p.A29= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100704155; called by muse, mutect2
- MASP1 | c.1303+5133T>A | Intron (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99962505; called by muse, mutect2, varscan2
